Surgical pathology report (de-identified scan), TCGA case TCGA-BR-A4J7, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-A4J7-01A (Primary Tumor).

Gross Description: In antrum-pylorus, there is a central ulcerated tumor with 7x5x2cm in size, firm and myxoid gray surface.

Microscopic Description: Mucosa is ulcerated. The tumor is composed of pools of extracellular mucin that contain malignant epithelium as cord or acinar or adenoid structures or glands or signet ring cells. Tumor is invasion in serosa. Nuclei are hyperchromatic and irregular enlarged with prominent nucleoli. Mitoses are present.

Diagnosis Details: Mucinous Adenocarcinoma, infiltrating serosa.

Comments:

Formatted Path Reports: STOMACH TISSUE CHECKLIST

Specimen type: Gastrectomy

Tumor site: Antrum

Tumor size: 7 x 5 x 2 cm

Tumor features: Ulcerated

Histologic type: Mucinous adenocarcinoma

Histologic grade: Poorly differentiated

Tumor extent: Serosa (visceral peritoneum)

Lymph nodes: Not specified

Lymphatic invasion: Not specified

Venous invasion: Not specified

Perineural invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

1CD-0-3

adenocarcinoma, mucinoma, NOS 8480/3

Site - stomach, antrum C16.3

hw
10/24/12

Source: NCI Genomic Data Commons file 9f982a84-2bed-4724-afc9-73fd528c6328 (TCGA-BR-A4J7.AD4F9754-BE94-4ECD-869C-AE2A9DF457CB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).